Gene-level copy-number profile of tumor specimen TCGA-D7-A4YY-01A from TCGA case TCGA-D7-A4YY, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 61.0 years (22,287 days).
Specimen TCGA-D7-A4YY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.fe232cb3-d6c2-494e-82cd-2fd40362090f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-A4YY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5d87f96d-1f2b-4042-90e9-6fae4a7eb54d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 170; copy number 1: 8,924; copy number 2: 49,296; copy number 3: 1,284; copy number 4: 141.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-A4YY-01A-11D-A253-01): tumor purity 0.75, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 139 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,747,277–61,251,459, 1 gene (within-gene range 0–1): FHIT.
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr6:17,224,243–17,382,120, 3 genes: AL136305.1, RBM24, AL034372.1.
- chr6:32,718,005–32,969,094, 17 genes (within-gene range 0–1): AL662789.1, HLA-DQB3, HLA-DQA2, MIR3135B, HLA-DQB2, HLA-DOB, AL669918.1, TAP2, PSMB8, PSMB8-AS1, PSMB9, TAP1, PPP1R2P1, HLA-Z, HLA-DMB, AL645941.2, HLA-DMA.
- chr6:50,514,035–50,773,033, 3 genes: AL360175.1, AL135908.1, TFAP2D.
- chr6:57,314,805–57,961,501, 11 genes (within-gene range 0–2): PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680.
- chr6:57,967,687–58,073,134, 2 genes: GAPDHP15, AL390237.1.
- chr6:74,069,451–74,734,319, 5 genes (within-gene range 0–1): AL357507.1, AL357563.1, AL356277.3, AL356277.1, AL356277.2.
- chr6:86,937,528–87,265,943, 10 genes (within-gene range 0–1): HTR1E, RPL7P29, MTHFD2P2, AL138827.1, RN7SKP209, CGA, RCN1P1, AL139274.2, ZNF292, AL139274.1.
- chr6:117,907,264–118,317,676, 2 genes (within-gene range 0–1): SLC35F1, AL450405.1.
- chr7:57,402,181–63,422,053, 61 genes (broad region; genes not listed).
- chr10:29,289,061–29,409,366, 2 genes: LYZL1, AL158167.1.
- chr10:67,334,123–67,334,882, 1 gene: RPL7AP51.
- chr12:42,615,221–43,054,386, 10 genes: LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5.
- chr12:45,718,046–45,727,775, 1 gene: AC008124.1.
- chr16:78,525,189–78,796,362, 4 genes: AC046158.4, AC046158.2, AC046158.3, AC009141.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,534. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
